Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7ES, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7ES-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:

History of abdominal mass. Biopsy spindle cell neoplasm with myxoid features.

Specimens Submitted:

- 1: Right retroperitoneal liposarcoma, right kidney, right colon
- 2: Additional retroperitoneal nodule
- 3: Retroperitoneal muscle and fat
- 4: Retroperitoneal lymph node

DIAGNOSIS:

1. Right retroperitoneal liposarcoma, right kidney, right colon, excision:
- Dedifferentiated liposarcoma.
- Grossly the tumor was present as two masses measuring 22 x 22 x 11.5 cm and 5.2 x 4.1 x 4 cm, respectively.
- The dedifferentiated component predominates (>50%) and is composed of high grade undifferentiated morphology with large areas of necrosis in the smaller nodule and mostly low grade myxofibrosarcoma-like morphology in the larger mass.
- Areas of well-differentiated liposarcoma are also present.
- Tumor does not involve kidney parenchyma, small bowel and right colon.
- Grossly the tumor mass was surrounded by an intact serosal surface, which represents the surgical margin.
2. Additional retroperitoneal nodule, excision:
- Reactive lymph node with obstructive-type lymphangiectasia
- No evidence of malignancy
3. Retroperitoneal muscle and fat, excision:
- Fragments of skeletal muscle and fibroadipose tissue
- No evidence of malignancy
4. Retroperitoneal lymph node, excision:
- Six reactive lymph nodes with sinus histiocytosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD-0-3

Liposarcoma, dedifferentiated
885813

Site: Retroperitoneum
C48.0

JW 9/26/13

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Page 2 of 4

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled right retroperitoneal liposarcoma, right kidney, and right colon. The entire specimen measures 41.5 x 27.2 x 11.0 cm. It consists of two masses; a large mass measuring 22 x 22 x 11.5 cm and another smaller mass measuring 5.2 x 4.1 x 4 cm. Also identified are right kidney, measuring 11.4 x 6.2 x 2.1 cm; and right colon measuring 21 cm in length. The average circumference of the colon is 8.7 cm and the wall thickness ranges from 0.2 to 0.3 cm. Appendix is identified and measures 4.5 x 0.3 x 0.3 cm. A nodule measuring 1.5x1 x1cm is identified adherent to the wall of colon. The cut section is tan white and homogenous. The right kidney is adherent to the large mass while the right colon is located 5.6 cm from the capsule of the large mass. The stump of the renal vein measures 1.3 cm and that of renal artery measures 0.7 cm. The ureter measures 17 cm in length. The ureter appears to be embedded within the large mass. The bowel is opened out along the antimesenteric border to reveal a thinned out bowel mucosa. No other gross abnormalities are identified. The cut section of appendix shows obliterated lumen due to fibrosis. The kidney on cut section shows grossly unremarkable renal parenchyma; which is clearly demarcated from the large mass. The large mass is serially sectioned to reveal a tan-yellow homogenous circumscribed cut surface. Only rare foci of hemorrhage and necrosis (less than 5%) are identified. The smaller mass is a serially sectioned to reveal a variegated cut surface with areas of hemorrhage and necrosis.

Summary of sections:

P = Proximal margin colon
D = Distal margin colon
APX = appendix
RVA = renal vein and artery margin
SM = smaller mass
KU = Ureter margin
LM = Large mass
NK = Normal kidney
BN = Bowel nodule
PBF = Peri-bowel fat

2) The specimen is received in formalin, labeled "additional retroperitoneal nodule", and consists of a 4.5 x 2.2 x 1.1 cm gray purple nodular portion of rubbery soft smooth tissue. Sectioning reveals gray to white-tan to gray purple soft cut surfaces. The specimen is entirely submitted.

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 4

Summary of sections:

U - undesignated

3) The specimen is received in formalin, labeled "retroperitoneal muscle and fat", and consists of a 5.4 x 3.2 x 1.4 cm aggregate of three portions of gray purple rubbery skeletal muscle and membranous rubbery tissue partially surfaced by mucosa, and with attached yellow-tan adipose tissue. Representative sections are submitted.

Summary of sections:

U - undesignated

4) The specimen is in formalin, labeled "retroperitoneal lymph node", and consists of a 4.7 x 2.1 x 1.3 cm irregular portion of gray purple rubbery tissue. Four gray-tan rubbery lymph nodes identified ranging from 0.7 up to 3.2 cm in greatest dimension. All identifiable lymph nodes are submitted.

Summary of sections:

LN - intact lymph nodes (2)

BLN - bisected lymph node (1)

SLN - sectioned lymph node (1)

Summary of Sections:

Part 1: Right retroperitoneal liposarcoma, right kidney, right colon

Block	Sect.	Site	PCs
1	APX	4	
1	BN	1	
1	D	2	
1	KU	1	
11	LM	22	
1	NK	1	
1	P	1	
1	PBF	2	
1	RVA	3	
3	SM	6	

Part 2: Additional retroperitoneal nodule

Block	Sect.	Site	PCs
5	U	6	

Part 3: Retroperitoneal muscle and fat

Block	Sect.	Site	PCs
2	U	3	

Part 4: Retroperitoneal lymph node

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 4 of 4

Block	Sect.	Site	PCs
1	BLN	2	
1	LN	2	
3	SLN	4	

** End of Report **

Source: NCI Genomic Data Commons file d1644c6c-0707-4cf1-a022-9866ecec2037 (TCGA-DX-A7ES.FB8CFADC-ABF9-4CEC-BFA6-7E54A84F7492.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).